Somatic mutation profile of tumor specimen TCGA-17-Z019-01A (aliquot TCGA-17-Z019-01A-01W-0746-08) from TCGA case TCGA-17-Z019, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14f8f26a-727c-44dc-8f37-f5d1d4378e04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z019-11A (Solid Tissue Normal), aliquot TCGA-17-Z019-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/826ebf4e-af4e-426f-a779-e69d366a104c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP10 | c.458A>T p.Y153F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs535209932; called by muse, varscan2
- LRP4 | c.1123dup p.A375Gfs*24 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs777522999; called by pindel, varscan2
